TCGA case TCGA-B2-5639 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/73cb1350-7590-4f79-bb86-3f395466652e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 46 years; Vital status: Dead; Days to death: 1,003 days (2.7 years).

Diagnoses (3)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 46.7 years (17,045 days); Year of diagnosis: 2010; AJCC pathologic T: T3; AJCC pathologic N: NX; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 31 days; Days to treatment end: 37 days; Treatment dose: 2,000 cGy; Course number: 1; Number of fractions: 5; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temsirolimus; Treatment intent type: Adjuvant; Days to treatment start: 74 days; Days to treatment end: 158 days; Number of cycles: 11; Treatment dose: 275 mg; Prescribed dose: 25; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pazopanib Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 177 days; Number of cycles: 241; Treatment outcome: Treatment Ongoing; Prescribed dose: 200; Prescribed dose units: mg; Route of administration: Oral.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 47.1 years (17,208 days); Days to diagnosis: 163 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 49.0 years (17,896 days); Days to diagnosis: 851 days (2.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (7 entries)
- Day 163 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 248 days; Disease response: With Tumor.
- Days to follow up: 417 days (1.1 years); Disease response: With Tumor.
- Day 851 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,003 days (2.7 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Recurrence/Progression.
- Karnofsky performance status: 70.

Molecular and laboratory tests
- Platelets: Normal.
- Hemoglobin: Normal.
- Leukocytes: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B2-5639-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 0.9; Shortest dimension: 0.9.
  Slide TCGA-B2-5639-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-B2-5639-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-B2-5639-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B2-5639-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-B2-5639-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 0.9; Shortest dimension: 0.8.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: Yes; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Lymph nodes examined: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Torisel.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 2; Pharmaceutical therapy drug name: Votrient; Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Follow-up form 1: New tumor event surgery: No; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; Performance status timing: At Recurrence/Progression Of Disease.
- Follow-up form 2: Lost to follow-up: No; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Patient received palliative neo-adjuvant radiation to the field where tumor was located.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,003 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,003 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 163 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B2-5639-01A-01D-1530-01): tumor purity 0.6, ploidy 2.04, whole-genome doublings 0.
